Somatic mutation profile of tumor specimen TCGA-QC-AA9N-01A (aliquot TCGA-QC-AA9N-01A-11D-A38Z-09) from TCGA case TCGA-QC-AA9N, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 53.1 years (19,395 days).
Specimen TCGA-QC-AA9N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9410581-9c71-4e6f-9f8e-5ac1f5563641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QC-AA9N-10A (Blood Derived Normal), aliquot TCGA-QC-AA9N-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e29264aa-3efd-4923-9ee9-4f9b2284b749

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 2, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AACS | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55539167; called by muse, mutect2, varscan2
- ATP1A2 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767896, COSV100768224; called by muse, mutect2, varscan2
- ATRX | c.2417del p.K806Rfs*16 | Frame Shift Del (DEL) | VAF 31/66 reads (47%) | catalogued as COSV100970906; called by mutect2, pindel, varscan2
- CABCOCO1 | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 44/118 reads (37%) | catalogued as COSV100357933; called by muse, mutect2, varscan2
- CLVS2 | c.724C>G p.P242A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV51559258, COSV51560504, COSV99252977; called by muse, mutect2, varscan2
- COL17A1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs529850690, COSV62225286; called by muse, mutect2, varscan2
- DCP2 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV101203917; called by muse, mutect2, varscan2
- DNAH9 | c.4208C>G p.T1403S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV99306330; called by muse, mutect2, varscan2
- F5 | c.6160C>A p.L2054I | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100889146; called by muse, varscan2
- FASN | c.4870A>T p.T1624S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100147935; called by muse, mutect2, varscan2
- FBN2 | c.7662T>A p.F2554L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99328295; called by muse, mutect2, varscan2
- FIZ1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684622; called by muse, mutect2, varscan2
- GALNT14 | c.743-1G>A p.X248_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100204922; called by mutect2, varscan2
- MBP | c.604C>G p.H202D (on ENST00000355994 / NM_001025101.2; = p.H95D on NM_002385.3) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV100592720; called by muse, mutect2, varscan2
- MROH2B | c.2066T>A p.L689H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.614); catalogued as COSV101270739, COSV68183222; called by muse, mutect2, varscan2
- NUDT1 | c.300G>C p.E100D (on ENST00000397048 / NM_198952.1; = p.E77D on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99770940; called by muse, mutect2, varscan2
- NWD1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV100342899; called by muse, mutect2, varscan2
- OR2G6 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100598205; called by muse, mutect2, varscan2
- OSBPL1A | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs775226164, COSV100111984; called by muse, mutect2, varscan2
- PER2 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs760214421, COSV99612113; called by muse, mutect2, varscan2
- PREX1 | c.2166G>T p.Q722H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100906468; called by muse, mutect2, varscan2
- PRSS55 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.035); catalogued as COSV100153806, COSV99073618; called by muse, mutect2, varscan2
- RALYL | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs772399055, COSV72822681; called by muse, mutect2, varscan2
- SEMA6D | c.1322T>C p.V441A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100317151; called by muse, mutect2, varscan2
- TP53TG5 | c.805A>G p.R269G | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.327); catalogued as COSV99713902; called by muse, mutect2, varscan2
- TTC17 | c.2368G>C p.G790R | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.296); catalogued as COSV99235461; called by muse, mutect2, varscan2
- TTC26 | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV100571040; called by muse, mutect2, varscan2
- ZNF521 | c.800A>G p.E267G | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.842); catalogued as COSV100832484; called by muse, mutect2, varscan2
- TSC2 | c.1651_1678del p.A551* | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel
- ACLY | c.3045C>G p.T1015= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100044366; called by muse, mutect2, varscan2
- CCDC141 | c.1761C>A p.T587= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV99836963; called by muse, varscan2
- CCDC43 | c.414G>C p.V138= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100189005; called by muse, mutect2, varscan2
- DNAH10 | c.11667G>A p.Q3889= (on ENST00000409039; = p.Q3828= on NM_207437.3) | Silent (SNP) | VAF 43/119 reads (36%) | catalogued as COSV101292336; called by muse, mutect2, varscan2
- EIF1AX | c.45T>C p.G15= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV100792180; called by muse, mutect2, varscan2
- ELN | c.21G>A p.A7= | Silent (SNP) | VAF 42/67 reads (63%) | catalogued as rs569660857, COSV99332746; called by muse, mutect2, varscan2
- HDAC9 | c.333A>G p.Q111= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV101286821; called by muse, mutect2, varscan2
- MSLNL | c.1224C>A p.A408= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99558396; called by muse, mutect2
- MX1 | c.294C>G p.G98= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99912710; called by muse, mutect2, varscan2
- NBEA | c.7776G>A p.K2592= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100081320; called by muse, mutect2, varscan2
- OR5J2 | c.420G>A p.K140= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100399078, COSV56623613; called by mutect2, varscan2
- SLC17A3 | c.304-124C>T | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs1440213880, COSV100399238; called by muse, mutect2, varscan2
